Somatic mutation profile of tumor specimen TCGA-GL-A59R-01A (aliquot TCGA-GL-A59R-01A-11D-A26P-10) from TCGA case TCGA-GL-A59R, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 79.5 years (29,046 days).
Specimen TCGA-GL-A59R-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d1db0ffa-ac8c-45a5-92bb-5293be82efc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GL-A59R-10A (Blood Derived Normal), aliquot TCGA-GL-A59R-10A-01D-A26P-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0659f616-6201-4e61-accc-2ecb14068cc5

The open-access MAF lists 107 somatic variants for this specimen: 77 protein-altering or splice-affecting, 22 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 22, Frame Shift Del 11, Nonsense Mutation 5, In Frame Del 4, Frame Shift Ins 4, Intron 4, 3'UTR 3, Splice Region 2, Splice Site 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASS | c.2584G>T p.G862W | Missense Mutation (SNP) | VAF 21/221 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62790058; called by muse, mutect2
- ACSM1 | c.760T>A p.L254I | Missense Mutation (SNP) | VAF 72/186 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as COSV54635950; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4954G>A p.V1652M | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV51847298; called by muse, mutect2, varscan2
- ARID2 | c.2977A>T p.T993S | Missense Mutation (SNP) | VAF 107/363 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.039); catalogued as COSV57603944; called by muse, mutect2, varscan2
- AXDND1 | c.316C>G p.R106G | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs577148644, COSV62642783, COSV62647866; called by muse, mutect2, varscan2
- CAPN13 | c.535T>C p.S179P | Missense Mutation (SNP) | VAF 52/130 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54430872; called by muse, mutect2, varscan2
- CASS4 | c.2217C>A p.H739Q | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.033); catalogued as COSV64386533; called by muse, mutect2, varscan2
- CIT | c.3713A>G p.K1238R | Missense Mutation (SNP) | VAF 79/148 reads (53%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.98); catalogued as COSV55869166; called by muse, mutect2, varscan2
- COL18A1 | c.199C>G p.R67G | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV62700991, COSV62701918, COSV62703565; called by muse, mutect2, varscan2
- CTSV | c.261A>C p.E87D | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52344808; called by muse, mutect2, varscan2
- DDX58 | c.2430C>A p.C810* | Nonsense Mutation (SNP) | VAF 4/45 reads (9%) | catalogued as COSV59380069; called by muse, mutect2, varscan2
- DNAH5 | c.7132G>T p.E2378* | Nonsense Mutation (SNP) | VAF 53/119 reads (45%) | catalogued as COSV54225388, COSV54253741; called by muse, mutect2, varscan2
- DXO | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV61713653; called by muse, mutect2, varscan2
- EP300 | c.3707del p.N1236Mfs*41 | Frame Shift Del (DEL) | VAF 46/134 reads (34%) | catalogued as COSV54340534; called by mutect2, pindel, varscan2
- FAM161A | c.902A>G p.K301R | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.192); catalogued as COSV56766110; called by muse, mutect2, varscan2
- FASTKD3 | c.746A>G p.E249G | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.231); catalogued as COSV52943934; called by muse, mutect2, varscan2
- FOXP2 | c.1714G>A p.V572I | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV63486201; called by muse, mutect2, varscan2
- FSIP2 | c.18686T>C p.I6229T | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs377239551; called by muse, mutect2
- GAB4 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.32); catalogued as rs1232493988, COSV68753734; called by muse, mutect2, varscan2
- GIGYF1 | c.2815G>A p.D939N | Missense Mutation (SNP) | VAF 6/82 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as rs1225569414, COSV51941897; called by muse, mutect2
- GPHN | c.2096G>A p.R699H (on ENST00000315266 / NM_001377519.1; = p.R732H on NM_020806.5) | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs756728918, COSV59480708; called by muse, mutect2, varscan2
- JAK2 | c.2048G>T p.R683I | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67581394, COSV67592547, COSV67612512; called by muse, mutect2, varscan2
- KIAA1549 | c.4126C>A p.P1376T | Missense Mutation (SNP) | VAF 67/246 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54314371; called by muse, mutect2, varscan2
- KRT6B | c.355G>C p.A119P | Missense Mutation (SNP) | VAF 123/851 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.029); catalogued as COSV52883792; called by muse, mutect2, varscan2
- LGALS9 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 194/766 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.286); catalogued as COSV56348922; called by muse, mutect2, varscan2
- LRP6 | c.4572C>G p.H1524Q | Missense Mutation (SNP) | VAF 36/152 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.177); catalogued as COSV53787557; called by muse, mutect2, varscan2
- MET | c.3208G>A p.V1070M | Missense Mutation (SNP) | VAF 116/187 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs760285693, COSV59261508; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MET | c.3209T>G p.V1070G | Missense Mutation (SNP) | VAF 114/185 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59257121, COSV59259138, COSV59261515; called by muse, mutect2, varscan2
- NAV3 | c.6446+1G>C p.X2149_splice (on ENST00000397909 / NM_001024383.2; = p.X2127_splice on NM_014903.6) | Splice Site (SNP) | VAF 12/25 reads (48%) | catalogued as COSV57080525; called by muse, mutect2, varscan2
- NEB | c.3245C>G p.A1082G | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.837); catalogued as COSV51417803, COSV51462841; called by muse, varscan2
- NFASC | c.1993T>G p.F665V (on ENST00000339876 / NM_001378329.1; = p.F661V on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/290 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV58365772; called by muse, varscan2
- P4HA1 | c.805C>T p.Q269* | Nonsense Mutation (SNP) | VAF 33/61 reads (54%) | catalogued as COSV54958227, COSV54961551; called by muse, mutect2, varscan2
- PGK2 | c.1108G>C p.V370L | Missense Mutation (SNP) | VAF 50/175 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV59162744, COSV59163893; called by muse, mutect2, varscan2
- PLXNB1 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV56489697; called by muse, mutect2, varscan2
- REXO1 | c.3167C>G p.T1056S | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs200984356, COSV50075309, COSV50078092; called by muse, varscan2
- RTKN | c.791T>C p.L264P (on ENST00000272430 / NM_001015055.2; = p.L251P on NM_033046.2) | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51963268; called by muse, mutect2, varscan2
- RUFY3 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.62); catalogued as COSV56913678; called by muse, mutect2, varscan2
- SCN11A | c.657G>C p.L219F | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); catalogued as COSV56570523; called by muse, mutect2, varscan2
- SETD1A | c.1223C>A p.S408Y | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); catalogued as COSV52687795; called by muse, mutect2, varscan2
- SF3B1 | c.2746A>G p.T916A | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as COSV59214308; called by muse, mutect2, varscan2
- SHLD2 | c.665C>G p.S222* | Nonsense Mutation (SNP) | VAF 38/108 reads (35%) | catalogued as COSV53954845; called by muse, mutect2, varscan2
- SIX4 | c.1108A>T p.I370F | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as COSV53669621; called by muse, mutect2, varscan2
- SKIL | c.794A>T p.E265V | Missense Mutation (SNP) | VAF 60/174 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52059894; called by muse, mutect2, varscan2
- SLCO4A1 | c.1878G>A p.G626= | Splice Region (SNP) | VAF 13/19 reads (68%) | catalogued as COSV53890967; called by muse, mutect2, varscan2
- SMARCD2 | c.1556G>T p.R519M | Missense Mutation (SNP) | VAF 108/196 reads (55%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); catalogued as COSV56739336; called by muse, mutect2, varscan2
- SRGAP1 | c.2420C>G p.S807* | Nonsense Mutation (SNP) | VAF 137/224 reads (61%) | catalogued as COSV61898121; called by muse, varscan2
- THAP11 | c.261G>T p.E87D | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV54646084; called by muse, mutect2, varscan2
- TMEM159 | c.393G>C p.W131C | Missense Mutation (SNP) | VAF 54/115 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.912); catalogued as COSV51785649; called by muse, mutect2, varscan2
- TTC4 | c.288G>C p.K96N | Missense Mutation (SNP) | VAF 52/145 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as COSV100988438, COSV64884674; called by muse, mutect2, varscan2
- TTN | c.14621T>G p.V4874G (on ENST00000591111; = p.V3947G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/137 reads (44%) | PolyPhen possibly damaging (0.76); catalogued as COSV60068895; called by muse, mutect2, varscan2
- TTN | c.14620G>T p.V4874L (on ENST00000591111; = p.V3947L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/137 reads (43%) | PolyPhen benign (0.067); catalogued as COSV60068906; called by muse, mutect2, varscan2
- UBE2N | c.185A>T p.Y62F | Missense Mutation (SNP) | VAF 67/326 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58867772; called by muse, mutect2, varscan2
- UMODL1 | c.3653G>T p.R1218L (on ENST00000408910 / NM_001004416.2; = p.R1346L on NM_173568.3) | Missense Mutation (SNP) | VAF 98/230 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV101252695, COSV68569828; called by muse, mutect2, varscan2
- VPS13A | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT tolerated (0.99); PolyPhen benign (0.062); catalogued as COSV62430090; called by muse, mutect2, varscan2
- VWA8 | c.1317G>A p.M439I | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs1275438476, COSV55697025; called by muse, mutect2, varscan2
- XPO1 | c.3182A>G p.N1061S | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.963); catalogued as COSV68946005; called by muse, mutect2, varscan2
- ZP2 | c.988C>A p.L330I | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.563); catalogued as COSV54813943; called by muse, mutect2, varscan2
- ZSWIM6 | c.3564G>T p.Q1188H | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV53172520; called by muse, mutect2, varscan2
- ALG6 | c.254del p.Y85Lfs*6 | Frame Shift Del (DEL) | VAF 15/36 reads (42%) | called by mutect2, pindel, varscan2
- BCL2L14 | c.708_709del p.F237Pfs*34 | Frame Shift Del (DEL) | VAF 68/268 reads (25%) | called by mutect2, pindel
- CNTF | c.577del p.Y193Ifs*11 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | called by mutect2, pindel, varscan2
- CSE1L | c.1936_1937dup p.L646Ffs*22 | Frame Shift Ins (INS) | VAF 13/61 reads (21%) | called by mutect2, pindel, varscan2
- DHTKD1 | c.2736dup p.I913Yfs*34 | Frame Shift Ins (INS) | VAF 30/87 reads (34%) | called by mutect2, pindel, varscan2
- EML5 | c.1875_1876insA p.V626Sfs*7 | Frame Shift Ins (INS) | VAF 15/39 reads (38%) | called by mutect2, pindel, varscan2
- KRTAP19-7 | c.22del p.Y8Mfs*4 | Frame Shift Del (DEL) | VAF 86/219 reads (39%) | called by mutect2, pindel, varscan2
- LRPAP1 | c.63_77del p.F22_W26del | In Frame Del (DEL) | VAF 10/29 reads (34%) | called by mutect2, pindel
- MDN1 | c.2717del p.Y906Lfs*2 | Frame Shift Del (DEL) | VAF 8/38 reads (21%) | called by mutect2, varscan2
- PCDHB10 | c.1284_1288delinsT p.P429Gfs*2 | Frame Shift Del (DEL) | VAF 38/142 reads (27%) | called by pindel, varscan2*
- RAF1 | c.226del p.M76* | Frame Shift Del (DEL) | VAF 49/125 reads (39%) | called by mutect2, pindel, varscan2
- RELA | c.795_807del p.V266Cfs*44 | Frame Shift Del (DEL) | VAF 26/84 reads (31%) | called by mutect2, pindel, varscan2
- RYR3 | c.11844del p.Q3950Kfs*30 (on ENST00000389232; = p.Q3951Kfs*30 on NM_001036.6) | Frame Shift Del (DEL) | VAF 41/90 reads (46%) | called by mutect2, pindel, varscan2
- TCTN2 | c.82+7A>G | Splice Region (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2, varscan2
- TDRD1 | c.40_45del p.N14_L15del | In Frame Del (DEL) | VAF 33/82 reads (40%) | called by mutect2, pindel, varscan2
- TRAF3IP2 | c.426del p.F142Lfs*63 | Frame Shift Del (DEL) | VAF 26/87 reads (30%) | called by mutect2, pindel, varscan2
- TSKU | c.991_996del p.S331_S332del | In Frame Del (DEL) | VAF 6/11 reads (55%) | called by mutect2, varscan2
- WWP1 | c.1636delinsAATTTTTT p.G546Nfs*5 | Frame Shift Ins (INS) | VAF 14/108 reads (13%) | called by pindel, varscan2*
- ZFP36L1 | c.750_776del p.F251_A259del | In Frame Del (DEL) | VAF 10/54 reads (19%) | called by mutect2, pindel
- AASS | c.2583T>C p.Y861= | Silent (SNP) | VAF 21/220 reads (10%) | catalogued as rs777824271, COSV62790062; called by muse, mutect2
- ACCSL | c.1446C>T p.L482= | Silent (SNP) | VAF 57/121 reads (47%) | catalogued as COSV66581249; called by muse, mutect2, varscan2
- ANK1 | c.4027C>T p.L1343= | Silent (SNP) | VAF 51/123 reads (41%) | catalogued as COSV55881929; called by muse, mutect2, varscan2
- AP1G2 | c.1941A>G p.P647= | Silent (SNP) | VAF 33/83 reads (40%) | catalogued as COSV55338219; called by muse, mutect2, varscan2
- ASH1L | c.8109C>T p.R2703= (on ENST00000368346 / NM_001366177.2; = p.R2698= on NM_018489.3) | Silent (SNP) | VAF 63/168 reads (38%) | catalogued as COSV64208061; called by muse, mutect2, varscan2
- ATP6V0D1 | c.210C>T p.I70= | Silent (SNP) | VAF 58/130 reads (45%) | catalogued as rs762823560, COSV52098042; called by muse, varscan2
- ATXN2 | c.2655T>C p.V885= (on ENST00000550104; = p.V725= on NM_002973.4) | Silent (SNP) | VAF 78/141 reads (55%) | catalogued as COSV66483289; called by muse, mutect2, varscan2
- CACNA2D2 | c.270C>A p.G90= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV56560507, COSV56563634; called by muse, varscan2
- CHD1L | c.1377C>A p.G459= | Silent (SNP) | VAF 27/79 reads (34%) | catalogued as COSV63613984; called by muse, mutect2, varscan2
- DNAH6 | c.3600T>G p.L1200= | Silent (SNP) | VAF 22/53 reads (42%) | catalogued as rs1188784059, COSV52861588; called by muse, mutect2, varscan2
- EXPH5 | c.5208A>C p.T1736= | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as COSV56202434; called by muse, mutect2, varscan2
- GRIP2 | c.1365C>T p.C455= (on ENST00000619221; = p.C358= on NM_001080423.4) | Silent (SNP) | VAF 23/35 reads (66%) | catalogued as rs1310567401, COSV56121484; called by muse, mutect2, varscan2
- JMJD1C | c.2889T>C p.F963= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs932844457, COSV59514975; called by muse, mutect2
- LMNA | c.1638A>C p.S546= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV61542970; called by muse, mutect2, varscan2
- NISCH | c.549C>T p.F183= | Silent (SNP) | VAF 18/279 reads (6%) | catalogued as COSV61899969; called by muse, mutect2
- NSUN2 | c.2175C>T p.T725= | Silent (SNP) | VAF 62/137 reads (45%) | catalogued as rs930773662, COSV52954515; ClinVar: likely benign; called by muse, mutect2, varscan2
- PHACTR1 | c.1332C>A p.P444= | Silent (SNP) | VAF 82/175 reads (47%) | catalogued as COSV60667139; called by muse, mutect2, varscan2
- RBBP8 | c.525G>A p.R175= | Silent (SNP) | VAF 41/126 reads (33%) | catalogued as COSV59092705; called by muse, mutect2, varscan2
- TMC4 | c.855C>A p.S285= (on ENST00000617472 / NM_001145303.3; = p.S279= on NM_144686.4) | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV56599887; called by muse, mutect2, varscan2
- TRPM4 | c.3369G>T p.T1123= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as rs747058283, COSV53262881; called by muse, mutect2, varscan2
- WIPI1 | c.396G>A p.L132= | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as rs778449594, COSV50930072; called by muse, mutect2, varscan2
- ZBTB10 | c.1347T>C p.S449= | Silent (SNP) | VAF 20/61 reads (33%) | catalogued as COSV66947488; called by muse, mutect2, varscan2
- AOX1 | c.*3C>A | 3'UTR (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99613674; called by muse, mutect2, varscan2
- GRHPR | c.734+165C>A | Intron (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
- LLGL2 | c.-11G>C | 5'UTR (SNP) | VAF 41/133 reads (31%) | catalogued as COSV99389987; called by muse, mutect2, varscan2
- RSAD1 | c.841-18T>C | Intron (SNP) | VAF 29/112 reads (26%) | called by muse, mutect2, varscan2
- SIRT2 | c.64-59del | Intron (DEL) | VAF 34/73 reads (47%) | called by mutect2, pindel, varscan2
- SLC5A3 | c.*2552A>G | 3'UTR (SNP) | VAF 19/48 reads (40%) | catalogued as COSV100757966; called by muse, mutect2, varscan2
- SOX4 | c.*2198T>A | 3'UTR (SNP) | VAF 22/44 reads (50%) | catalogued as COSV99782073; called by muse, mutect2, varscan2
- THAP12 | c.319-20T>C | Intron (SNP) | VAF 10/23 reads (43%) | called by muse, mutect2, varscan2
